Gene-level copy-number profile of tumor specimen TCGA-61-1913-01A from TCGA case TCGA-61-1913, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 48.1 years (17,575 days).
Specimen TCGA-61-1913-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.b3877e46-6cd0-4123-9909-2698a8f627ce.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-1913-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c35fcab7-f215-418e-8156-00545dd1e9f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 20,221; copy number 2: 35,321; copy number 3: 3,005; copy number 4: 385; copy number 5: 884.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-1913-01A-01D-0577-01): tumor purity 0.89, ploidy 1.8, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:140,103,583–140,131,780, 1 gene: LINC01853.
- chr20:46,997,596–46,998,488, 1 gene: GAPDHP54.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 884 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:146,909,685–147,370,656, 1 gene, copy number 5 (within-gene range 3–5): AC092957.1.
- chr3:146,996,607–177,011,067, 437 genes, copy number 5 (broad region; genes not listed).
- chr8:121,612,116–145,066,685, 446 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20,221. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
